CPTAC case C3L-03374 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/62bfcefd-ab89-4a9b-b4d1-f6c97de85807

Demographics
Sex at birth: male; Race: white; Year of birth: 1934; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Age at diagnosis: 82.9 years (30,274 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M1a; AJCC pathologic T: T4b; AJCC pathologic N: N2b; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IV; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 669 days (1.8 years); Progression or recurrence: no; Days to last follow up: 669 days (1.8 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 4; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (1 entry)
- Days to follow up: 669 days (1.8 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03374-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 375 days (1.0 years); Initial weight: 295 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03374-21: Section location: Trunk; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-03374-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 375 days (1.0 years); Initial weight: 306 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-03374-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 375 days (1.0 years); Method of sample procurement: Blood Draw.
